Somatic mutation profile of tumor specimen TCGA-DU-7009-01A (aliquot TCGA-DU-7009-01A-11D-2024-08) from TCGA case TCGA-DU-7009, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 32.5 years (11,854 days).
Specimen TCGA-DU-7009-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5292ec75-b425-491a-88f1-d74b6538752e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-7009-10A (Blood Derived Normal), aliquot TCGA-DU-7009-10A-01D-2024-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ae5c987-cc07-421b-bdd3-b05e66672b7d

The open-access MAF lists 16 somatic variants for this specimen: 14 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 11, Silent 2, Frame Shift Del 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 29/65 reads (45%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AFF2 | c.1748C>T p.P583L | Missense Mutation (SNP) | VAF 90/210 reads (43%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.506); catalogued as rs1199163045, COSV53992659; called by muse, mutect2, varscan2
- ANAPC15 | c.149A>G p.N50S | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV56192234; called by muse, mutect2, varscan2
- ATP6V1C2 | c.913C>T p.P305S | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.026); catalogued as COSV55361092; called by muse, mutect2, varscan2
- GPANK1 | c.985C>G p.L329V | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.068); catalogued as rs773028545, COSV63263844; called by muse, mutect2, varscan2
- GRIA3 | c.2638T>A p.Y880N | Missense Mutation (SNP) | VAF 53/136 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as COSV52063785; called by muse, mutect2, varscan2
- NIPBL | c.430C>T p.Q144* | Nonsense Mutation (SNP) | VAF 34/99 reads (34%) | catalogued as COSV56953543; called by muse, mutect2, varscan2
- OGT | c.3124G>A p.V1042I | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV65470042; called by muse, mutect2, varscan2
- SLC22A5 | c.847T>G p.W283G | Missense Mutation (SNP) | VAF 80/224 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM061981, CM993369, COSV55373302; called by muse, mutect2, varscan2
- SLC9A6 | c.1423C>T p.R475W | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65788159; called by muse, mutect2
- SRRM2 | c.3510A>T p.L1170F | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV57074405; called by muse, mutect2, varscan2
- ZMIZ1 | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.977); catalogued as COSV57890392; called by muse, mutect2
- AHCTF1 | c.6246dup p.L2083Tfs*6 (on ENST00000366508; = p.L2057Tfs*6 on NM_015446.5) | Frame Shift Ins (INS) | VAF 11/105 reads (10%) | called by mutect2, pindel, varscan2
- ARID1A | c.5930_5931del p.L1977Rfs*21 | Frame Shift Del (DEL) | VAF 27/64 reads (42%) | called by mutect2, pindel, varscan2
- ANO4 | c.1173T>A p.A391= (on ENST00000392977 / NM_001286615.2; = p.A356= on NM_178826.4) | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV54598616; called by muse, mutect2, varscan2
- PRUNE2 | c.2859C>T p.N953= | Silent (SNP) | VAF 10/145 reads (7%) | catalogued as rs758281726, COSV65042418, COSV65044639; called by muse, mutect2
